Somatic mutation profile of tumor specimen TCGA-B6-A401-01A (aliquot TCGA-B6-A401-01A-11D-A23C-09) from TCGA case TCGA-B6-A401, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.7 years (17,438 days).
Specimen TCGA-B6-A401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81df010d-dd73-4252-bc5b-d2796bd46f4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A401-10A (Blood Derived Normal), aliquot TCGA-B6-A401-10A-01D-A23C-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3318015-d537-4ebe-8edc-975ba5c5457f

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 24/40 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGEF40 | c.1408G>T p.G470* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV53882793; called by muse, mutect2, varscan2
- CDH15 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV57026263; called by muse, mutect2, varscan2
- FMR1 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782738200, COSV54423607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTATSF1 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV54480291; called by muse, mutect2, varscan2
- IFNA21 | c.206A>C p.N69T | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV66518642; called by muse, mutect2, varscan2
- ITGA6 | c.2464G>T p.A822S (on ENST00000442250; = p.A783S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.393); catalogued as COSV51227311; called by muse, mutect2
- KCNK5 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63989211; called by muse, mutect2, varscan2
- LRATD2 | c.738T>G p.S246R | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1485066677, COSV100513516; called by muse, mutect2
- MAP3K1 | c.3880_3884del p.E1294Kfs*13 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as COSV68122337; called by mutect2, pindel, varscan2
- MEPCE | c.1793del p.R598Pfs*18 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as COSV52769694; called by mutect2, pindel, varscan2
- PAX9 | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV64062145; called by muse, mutect2, varscan2
- PLEKHA8 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs555138725, COSV99321356; called by muse, mutect2
- R3HDM2 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV61292930; called by muse, mutect2, varscan2
- SHROOM2 | c.2264C>T p.T755I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66609346; called by muse, mutect2, varscan2
- SLITRK2 | c.2300C>A p.P767H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV59425200; called by muse, mutect2, varscan2
- TPRX1 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV59116810; called by muse, mutect2, varscan2
- NAIP | c.27C>A p.D9E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CIC | c.1092C>T p.D364= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs747213131, COSV50550011; called by muse, mutect2, varscan2
- DCAF5 | c.1914C>T p.S638= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV58461977; called by muse, mutect2, varscan2
- NFIL3 | c.465C>A p.S155= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- TNIK | c.2070G>T p.G690= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as COSV52689908, COSV99454895; called by muse, mutect2
- ZNRF1 | c.417G>A p.S139= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV57729128; called by muse, mutect2, varscan2
- KRT18P55 | n.1116G>A | RNA (SNP) | VAF 6/23 reads (26%) | catalogued as rs371488953; called by muse, mutect2, varscan2
